Gene-level copy-number profile of tumor specimen TCGA-DD-AADE-01A from TCGA case TCGA-DD-AADE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 50.6 years (18,482 days).
Specimen TCGA-DD-AADE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.13f5d16b-dac9-4d26-9d1a-7aa0284ce26f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54c1893c-5985-450e-b655-c0af3f691ca9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,929; copy number 2: 50,062; copy number 3: 2,091; copy number 4: 2,926; copy number 5: 4; copy number 6: 654; copy number 7: 125; copy number 8: 10; copy number 13: 1; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADE-01A-11D-A40Q-01): tumor purity 0.75, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 795 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:111,250,254–111,256,715, 1 gene, copy number 14 (within-gene range 2–14): CHIAP1.
- chr8:95,133,785–145,066,685, 788 genes, copy number 6–8 (broad region; genes not listed).
- chr9:14,790,635–14,791,158, 1 gene, copy number 13: AL512643.1.
- chr10:93,566,665–93,604,480, 1 gene, copy number 5 (within-gene range 2–5): FFAR4.
- chr12:54,455,950–54,548,243, 3 genes, copy number 5: GTSF1, NCKAP1L, AC068789.1.
- chr17:34,479,272–34,482,148, 1 gene, copy number 7: AC011193.1.

Autosomal genes at a single copy (total copy number 1): 1,508. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
